FM case AD15388 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/90a0f7c9-d3b3-4ab1-b9df-9793449dc73e

Male, 60.1 years: Small cell carcinoma, NOS (ICD-O-3 8041/3); metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 43% (pathologist estimate recorded by GDC). Sample type: Metastatic.
